Surgical pathology report (de-identified scan), TCGA case TCGA-98-A538, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - Alabama, specimen TCGA-98-A538-01A (Primary Tumor).

[page 1 of 3]
ICB-0-3

Carcinoma, squamous cell, NOS 807013

Site: Lung, @ upper lobe C34.1 hx 11/25/12

Patient Name	MR#	Observation Date
--------------	-----	------------------

SURGICAL PATHOLOGY CASE:

Diagnosis

- A. Lymph node, level IX, excision: - No tumor identified (0/3).
- B. Lymph node, level VIII, excision: - No tumor identified (0/1).
- C. Lymph node, level IV, excision: - No tumor identified (0/1).
- D. Lymph node, level VI, excision: - No tumor identified (0/1). - Calcified hyalinized nodule.
- E. Lymph node, level XII, excision: - No tumor identified (0/1).
- F. Lymph node, level XIII, excision: - No tumor identified (0/1).
- G. Lymph node, level VII, excision: - No tumor identified (0/4).
- H. Lymph node, level XI, excision: - No tumor identified (0/4).
- I. Lung, left upper lobe, bronchial margin, excision: No tumor identified (?).
- J. Lung, left upper lobe, excision: - Squamous cell carcinoma, moderately differentiated. - Tumor measures 7.0 cm in greatest dimension. - No lymphovascular invasion identified. - Surgical bronchial and vascular margins are negative for malignancy. - Two peribronchial lymph nodes negative for malignancy (0/2). - Pathologic staging: pT2bN0Mx.

Pathologist Comments

The lung parenchyma adjacent to the squamous cell carcinoma shows a few organizing pneumonia with BOOP like features. Review of the frozen section slides of specimen J show the BOOP-like features, but no tumor is identified in that particular section.

Clinical Information: The patient is a year old male with a history of lung cancer.

Frozen Section Diagnosis

IFS1 - Lung, left upper lobe, bronchial margin, excision: - No tumor seen.

JFS1 - Lung, left upper lobe, excision: - Fibrotic lung with atypia, no definitive tumor. - Additional sampling on permanent. (per

Gross Description

The specimens are received in ten containers, each labeled with the patient's name and medical record number. The first specimen is further designated as "level IX lymph node". It consist of two fragments of yellow/tan fibroadipose tissue measuring 1.1 x 0.8 x 0.2 and 1.0 x 0.5 x 0.4 cm. Blue surgical dye is noted in one of the tissue fragments. This tissue fragment is submitted in its entirety in cassette A1, and the remaining tissue fragment is submitted in cassettes A2.

The second specimen is additionally designated as "level VIII lymph node". It consist of a fragment of yellow/tan, fibroadipose tissue measuring 1.2 x 0.5 x 0.3 cm. A second smaller apparent lymph node is included which measures 0.6 cm in greatest dimension. One dissection of the larger tissue fragment reveals a single possible anthracotic lymph node measuring 0.6 cm. The entire specimen is submitted in cassette B1.

The third specimen is further designated as "level V lymph nodes". It consist of a single possible lymph node measuring 0.6 x 0.4 x 0.3 cm. The specimen is submitted whole in cassette C1.

The fourth specimen is additionally designated as "level VI lymph node". It consist of a single gray/tan possible lymph node measuring 1.7 x 0.5 x 0.4 cm. The specimen is bisected and submitted in its entirety in cassette D1.

The fifth specimen is further designated as "level XII lymph node". It consist of multiple possible gray/tan apparent lymph node measuring from 0.5 to 0.6 cm in greatest dimension. The specimen is submitted whole in cassette E1.

[page 2 of 3]
The sixth specimen is received in a container further designated as "level XIII lymph node". It consist of single brown-tan fragment of soft tissue measuring 0.4 x 0.4 x 0.3 cm. The entire specimen is submitted in cassette F1.

The seventh specimen is received in a container further designated as "level VII lymph node". It consist of multiple fragments of brown/tan, fibrofatty soft tissue measuring 1.7 x 1.2 x 0.4 cm. Dissection reveals four possible lymph nodes ranging in size from 0.5 to 1.1 cm in greatest dimension. The entire specimen is submitted for microscopic examination.

The eighth specimen is received in a container further designated as "level XI lymph node". It consist of multiple tan/brown fragments of soft tissue measuring 1.0 x 0.9 x 0.8 cm. Multiple small apparent lymph nodes are identified ranging in size from 0.3 to 0.6 cm in greatest dimension. The entire specimen is submitted for microscopic examination in cassette H1.

The ninth specimen is received in a single container further designated "bronchial margin". It consist of a single white/tan, fragment of soft tissue measuring 0.6 x 0.4 x 0.2 cm. This tissue was previously submitted for frozen section and will be resubmitted in its entirety for permanent section.

The tenth specimen is received in a container further designated as "left upper lobe". It consist of a lobe of lung measuring 18.0 x 8.5 x 6.5 cm. Also included within the container is an orange cassette marked J1. It consist of a frozen section remnant measuring 1.5 x 1.5 x 0.2 cm. The frozen section remnant is entirely resubmitted for permanent section examination. The specimen has been previously opened to reveal a heterogenous white/tan mass measuring 7.0 x 5.5 x 5.3 cm. The lesion appears to multi focally abut the surface; however, no gross invasion is identified. The mass shows multi focal areas of apparent hemorrhage and necrosis. The white/tan mass grossly appears to approach within 0.3 cm of the nearest stapled surgical resection margin. The staple line is inked blue and removed. Radial section demonstrating the relationship of the mass to the inked resection margin is submitted in cassette J4. Sectioning through the mass reveals multiple small cavities containing a yellow/brown purulent appearing fluid. A single darkly pigmented apparent lymph node is identified in the hilar region which measured approximately 2.1 x 1.0 x 0.5 cm.

Block Summary

A1, A2 - Level IX lymph node
B1 - Level VIII lymph node
C1 - Level V lymph node
D1 - Level VI lymph node
E1 - Level XII lymph node
F1 - Level XIII lymph node
G1 - Level VII lymph node, multiple node submitted whole
G2 - Level VII lymph node, single possible node bisected
G3 - Level VII lymph node, single possible lymph node submitted whole
H1 - Level XI lymph node
I1 - Bronchial margin, frozen section
J1 - Left upper lobe, frozen section
J2 - Shave of hilar resection margin
J3 - Shave of stapled surgical resection margin
J4-J8 - Representative sections of mass
J9 - Representative sections of uninvolved lung parenchyma
J10 - Single and large anthracotic lymph node, serially sectioned and entirely submitted

Microscopic Description: A microscopic examination has been performed.

SP Synoptic Report J: Thorax Lung

SPECIMEN: Lobe(s) of lung: left upper lobe
PROCEDURE: Lobectomy
SPECIMEN INTEGRITY: Intact
SPECIMEN LATERALITY: Left
TUMOR SITE: Upper lobe
TUMOR SIZE: Greatest dimension: 7.0 cm
TUMOR FOCALITY: Unifocal
HISTOLOGIC TYPE: Squamous cell carcinoma
HISTOLOGIC GRADE: G2: Moderately differentiated
VISCERAL PLEURA INVASION: Not identified
TUMOR EXTENSION: Not applicable
BRONCHIAL MARGIN: Uninvolved by invasive carcinoma

[page 3 of 3]
VASCULAR MARGIN: Uninvolved by invasive carcinoma
PARENCHYMAL MARGIN: Uninvolved by invasive carcinoma
PARIETAL PLEURAL MARGIN: Not applicable
CHEST WALL MARGIN: Not applicable
TREATMENT EFFECT: Not applicable
LYMPH-VASCULAR INVASION: Not identified
LYMPH NODES: Present
PRIMARY TUMOR (pT): pT2b: Tumor greater than 5 cm, but 7 cm or less in greatest dimension
REGIONAL LYMPH NODES (pN): pN0: No regional lymph node metastasis
DISTANT METASTASIS (pM): Not applicable

11/29/12

Source: NCI Genomic Data Commons file 9900567a-509a-4c1c-9866-474bf424cb7c (TCGA-98-A538.D297F1CF-8E9C-466C-8EE0-C589E5C74D29.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).